Surgical pathology report (de-identified scan), TCGA case TCGA-3B-A9HP, project TCGA-SARC (Sarcoma), tissue source site Moffitt Cancer Center, specimen TCGA-3B-A9HP-01A (Primary Tumor).

[page 1 of 2]
Pathology Report

Gender: F Service: Received:
Reported:
Submitting Physicians:
Pathologist:
Intraop Pathologist:
Performing Physician:

CLINICAL HISTORY:

-YEAR-OLD FEMALE WITH PELVIC MASS AND LEIOMYOSARCOMA ON BIOPSY.

PREOPERATIVE DIAGNOSIS:

PELVIC MASS WITH LEIOMYOSARCOMA ON BIOPSY.

SPECIMEN TYPE(S):

- A: RIGHT OVARY AND FALLOPIAN TUBE
- B: RIGHT PELVIC TUMOR
- C: LATERAL MARGIN
- D: UTERUS, CERVIX, LEFT TUBE AND OVARY

ICD O-3
Leiomyosarcoma NOS 8890/3
Site: Retroperitoneum C48.0
J 4/22/14

FINAL DIAGNOSIS:

- A. RIGHT OVARY AND FALLOPIAN TUBE, SALPINGO-OOPHORECTOMY:
Ovary with physiologic changes, negative for malignancy.
Fallopian tube with no significant pathologic changes.
- B. RIGHT PELVIC TUMOR, RESECTION:
Leiomyosarcoma, high grade.
Tumor size: 11.5 cm, 414 grams.
Tumor focally extends to inked surgical margin.
Tumor necrosis: Approximately 25%.
Negative for angiolymphatic invasion.

COMMENT: Microscopic section show a spindle cell neoplasm composed of markedly atypical spindle cells with increased mitosis, some apical and areas of necrosis. The necrotic areas are approximately 25% of the tumor. The prior core biopsy of the specimen reported the tumor cells to be positive for smooth muscle actin, desmin, vimentin, and SMMS-1 and are reported as negative for CD117, CD34, S-100, and pankeratin. The tumor cells are also reported as positive for ER, PR and EGFR.

- C. LATERAL MARGIN:
Leiomyosarcoma, high grade.
The tumor focally extends to the inked surgical margin.
- D. UTERUS, CERVIX, LEFT TUBE AND OVARY, HYSTERECTOMY WITH LEFT-SIDED SALPINGO-OOPHORECTOMY:
Inactive type endometrial, negative for malignancy.
Leiomyoma, intramural, see comment.
Mild chronic cervicitis and Nabothian cyst.
Ovary with physiologic changes.
Fallopian tube with no significant pathologic changes.

COMMENT: Sections of the uterus show intramural leiomyoma. There is no necrosis, increased mitosis or cytologic atypia.

I, _____, M.D. the attending pathologist, personally reviewed the entire pathology case and rendered the final diagnosis. Electronically signed out by

[page 2 of 2]
OTHER RELATED CLINICAL DATA:

NA

GROSS DESCRIPTION:

- A. Specimen received fresh. Specimen A labeled "right ovary and tube". The specimen consists of an 8.3 gram ovary with adjacent fragment of fimbriated fallopian tube. The fallopian tube measures 3.0 cm in length and up to 0.3 cm in diameter, and have a tan-pink, smooth, glistening, mildly congested serosa. The cut surface of the tube reveals pinpoint, grossly unremarkable lumen. The ovary measures 2.7 x 1.8 x 0.8 cm, and is grossly unremarkable. All tissue is submitted to the . Representative sections of the specimen are submitted in 3 cassettes as follows:
- A1: Fallopian tube
A2-A3: Representative sections of the ovary.
- B. Specimen B labeled "right pelvic tumor". The specimen consists of a 414 gram, 11.5 x 9.0 x 7.5 cm, irregular to ovoid, rubbery, grossly encapsulated tumor mass with a small amount of adjacent capsule tan-pale-yellow, soft, lobulated adipose tissue which is ranging from 0.1 to 0.5 cm in thickness. The surface of the tumor is tan-pink, focally hemorrhagic, smooth, glistening, and vacillated. Prior to sectioning the outer surface of the specimen is inked black. On sectioning the specimen revealed homogeneous tan-white to tan-pink, cut surface with several irregular areas of possible necrosis ranging from 0.1 to 1.1 cm in greatest dimension. Representative sections of the specimen are submitted to the . Representative sections of the specimen are submitted in 12 cassettes, B1-B12.
- C. Specimen C labeled "lateral margin". The specimen consists of a single, irregular, unoriented fragment of tan-pink to tan-red, focally hemorrhagic, rubbery-to-firm tissue, measuring 1.8 x 1.5 x 0.7 cm. Prior to sectioning the specimen is inked blue. The specimen is serially sectioned and submitted entirely in 3 cassettes, C1-C3.
- D. Specimen D labeled "uterus, cervix, left tube plus ovary". The specimen consists of a 110 gram uterus with adjacent lower uterine segment and cervix, and attached left fallopian tube and ovary. The uterus is with attached lower uterine segment and cervix measures 9.7 x 5.0 x 4.0 cm. The uterine body is covered with tan-pink, smooth, glistening, mildly congested serosa. Prior to sectioning the specimen, all the margins of resection are inked black. The external os of endocervical canal is patent and reveals a grossly unremarkable endocervical junction. The mucosa of the ectocervix is tan-pink, smooth, glistening, and grossly unremarkable. The endocervical canal measures up to 3.5 cm in length and reveals 0.6 cm in diameter lumen which is filled with moderate amount of transparent mucus. The endocervical canal is lined by tan-pink trabeculated mucosa. The endometrial cavity measures 3.0 x 2.0 x 0.4 cm and is lined by tan-pink, gelatinous endometrium, which is averaging 0.1 cm in thickness. The myometrium of the posterior wall reveals an irregular to ovoid, well-defined, rubbery intramural nodule measuring 1.8 x 1.3 x 1.0 cm. The cut surface of the nodule is tan-pink, whorled, and without evidence of necrosis or hemorrhage. The remaining myometrium of the anterior and posterior wall is grossly unremarkable, trabeculated, and averaging 1.7 cm in thickness. The left fimbriated fallopian tube measures 3.5 cm in length and up to 0.5 cm in diameter, and has tan-pink, smooth, glistening, mildly congested serosa. The cut surface of the tube reveals pinpoint grossly unremarkable lumen. The left ovary measures 2.3 x 1.3 x 0.7 cm and is grossly unremarkable. Representative sections of the specimen are submitted to the . Representative sections of the specimen are submitted in 10 cassettes, D1-D10, as follows:
- D1: Anterior cervix
D2: Posterior cervix
D3-D4: Anterior endomyometrium
D5-D6: Posterior endomyometrium with intramural nodule
D7-D8: Additional sections of posterior endomyometrium
D9: Left fallopian tube
D10: Left ovary.

Source: NCI Genomic Data Commons file 86ec6770-f1f4-4454-967a-d0a106cfe06b (TCGA-3B-A9HP.89CA5BFC-CC5B-4261-8502-FDB000DB89C8.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).